Somatic mutation profile of tumor specimen MP2PRT-PASWJK-TMP1-A (aliquot MP2PRT-PASWJK-TMP1-A-1-0-D-A81O-36) from MP2PRT case MP2PRT-PASWJK, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.5 years (1,267 days).
Specimen MP2PRT-PASWJK-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 432fc3d7-a741-44d0-acaa-0e845f46b726.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PASWJK-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PASWJK-NB1-A-1-0-D-A81O-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9758c34b-9161-415c-b748-222e19bd2c84

The open-access MAF lists 15 somatic variants for this specimen: 12 protein-altering or splice-affecting, 3 silent.
By variant classification: Missense Mutation 9, Silent 3, Nonsense Mutation 2, In Frame Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DENND2B | c.763C>T p.R255W | Missense Mutation (SNP) | VAF 126/629 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs777038380, COSV100567959; called by muse, mutect2, varscan2
- LATS2 | c.812G>A p.R271H | Missense Mutation (SNP) | VAF 161/462 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.019); catalogued as rs542237961, COSV66874113; called by muse, mutect2, varscan2
- RASSF6 | c.826C>T p.R276* (on ENST00000342081 / NM_201431.2; = p.R244* on NM_177532.5) | Nonsense Mutation (SNP) | VAF 26/159 reads (16%) | catalogued as rs776889884; called by muse, mutect2, varscan2
- RUNX1T1 | c.598G>A p.A200T (on ENST00000265814 / NM_001198628.1; = p.A173T on NM_004349.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 60/379 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as rs766588136, COSV56140268, COSV56144015; called by muse, mutect2, varscan2
- TRRAP | c.9406G>A p.E3136K (on ENST00000359863 / NM_001244580.1; = p.E3107K on NM_003496.3) | Missense Mutation (SNP) | VAF 36/128 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as COSV100722648, COSV62849388; called by muse, mutect2, varscan2
- EPHA10 | c.2312T>C p.L771P | Missense Mutation (SNP) | VAF 129/448 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FLT3 | c.2508_2509insGACCCTGGC p.I836_M837insDPG | In Frame Ins (INS) | VAF 25/142 reads (18%) | called by mutect2, pindel, varscan2
- NETO1 | c.619C>T p.R207* | Nonsense Mutation (SNP) | VAF 47/239 reads (20%) | called by muse, mutect2, varscan2
- RRAGD | c.328T>C p.F110L | Missense Mutation (SNP) | VAF 50/268 reads (19%) | SIFT tolerated (0.24); PolyPhen benign (0.435); called by muse, mutect2, varscan2
- TMEM200C | c.1370G>A p.R457H | Missense Mutation (SNP) | VAF 150/630 reads (24%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.948); called by muse, mutect2, varscan2
- YTHDF3 | c.997G>A p.G333R | Missense Mutation (SNP) | VAF 124/524 reads (24%) | SIFT tolerated (0.37); PolyPhen benign (0.108); called by muse, mutect2, varscan2
- ZNF84 | c.365C>G p.P122R | Missense Mutation (SNP) | VAF 21/107 reads (20%) | SIFT tolerated (0.26); PolyPhen benign (0.044); called by muse, mutect2, varscan2
- FAM149A | c.1308C>T p.R436= (on ENST00000356371 / NM_001367768.2; = p.R145= on NM_015398.3 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 56/291 reads (19%) | catalogued as rs114480943; called by muse, mutect2, varscan2
- RAN | c.441C>T p.Y147= | Silent (SNP) | VAF 57/196 reads (29%) | catalogued as rs373832485; called by muse, mutect2, varscan2
- SASS6 | c.1488G>A p.P496= | Silent (SNP) | VAF 66/220 reads (30%) | catalogued as rs779107653, COSV54928484; called by muse, mutect2, varscan2
